Somatic mutation profile of tumor specimen 0DL6SG from CCDI case PBBZDT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 12.3 years (4,483 days).
Specimen 0DL6SG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8884f12a-d1fd-4818-8e86-a55c2af0705d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DL6RM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f10b13af-d78d-475b-aeb3-26b209ee1153

The open-access MAF lists 71 somatic variants for this specimen: 53 protein-altering or splice-affecting, 6 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, 3'UTR 7, Silent 6, Nonsense Mutation 6, Intron 3, Frame Shift Ins 1, 5'UTR 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 387/639 reads (61%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- AP2A1 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 145/347 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1315493907, COSV100756276; called by muse, mutect2, varscan2
- CARD14 | c.2507C>T p.A836V | Missense Mutation (SNP) | VAF 151/557 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368705564; called by muse, mutect2, varscan2
- CORO7 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs762249901, COSV99228126; called by muse, mutect2, varscan2
- CSN2 | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 206/513 reads (40%) | catalogued as rs970814888, COSV61991864, COSV61992264; called by muse, mutect2, varscan2
- DST | c.2969G>A p.R990Q (on ENST00000361203 / NM_001374722.1; = p.R664Q on NM_001723.6) | Missense Mutation (SNP) | VAF 91/231 reads (39%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.947); catalogued as rs769812737; called by muse, mutect2, varscan2
- EPHA4 | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 103/361 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.959); catalogued as rs1443433118, COSV56038686; called by muse, mutect2, varscan2
- FLG | c.4690C>A p.P1564T | Missense Mutation (SNP) | VAF 153/370 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0.117); catalogued as COSV100911775, COSV64253172; called by muse, mutect2, varscan2
- FLNC | c.3485G>T p.G1162V | Missense Mutation (SNP) | VAF 132/594 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57964684; called by muse, mutect2, varscan2
- FRMD4B | c.1601G>A p.R534Q | Missense Mutation (SNP) | VAF 123/371 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199520789; called by muse, mutect2, varscan2
- HK3 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 167/650 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs563509390, COSV52845375; called by muse, mutect2, varscan2
- MCPH1 | c.2221C>T p.R741* | Nonsense Mutation (SNP) | VAF 89/544 reads (16%) | catalogued as rs374596700; called by muse, mutect2, varscan2
- MECP2 | c.1436C>T p.T479M | Missense Mutation (SNP) | VAF 105/127 reads (83%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as rs267608635, COSV57653472; ClinVar: benign; called by muse, mutect2, varscan2
- PAH | c.843-4T>A | Splice Region (SNP) | VAF 74/274 reads (27%) | catalogued as CD135061; called by muse, mutect2, varscan2
- PRB3 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 403/865 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs1490839468; called by muse, mutect2, varscan2
- RNF17 | c.3007G>T p.E1003* | Nonsense Mutation (SNP) | VAF 50/136 reads (37%) | catalogued as COSV99693919; called by muse, mutect2, varscan2
- SAMM50 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 75/175 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1034386294; called by muse, mutect2, varscan2
- TENM3 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 137/350 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs753633001, COSV69318349; called by muse, mutect2, varscan2
- TES | c.197T>C p.L66P | Missense Mutation (SNP) | VAF 87/350 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100829325; called by muse, mutect2, varscan2
- TSEN34 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777672748; called by muse, mutect2, varscan2
- ZNF474 | c.462C>G p.N154K | Missense Mutation (SNP) | VAF 168/544 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV56947759; called by muse, mutect2, varscan2
- BIRC7 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 205/720 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- BORA | c.1783G>A p.E595K (on ENST00000613797; = p.E520K on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 129/310 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- C6 | c.1720T>G p.W574G | Missense Mutation (SNP) | VAF 94/492 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CCDC115 | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 80/304 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- CEP295 | c.2402A>T p.K801I | Missense Mutation (SNP) | VAF 133/690 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- CLNK | c.1267A>T p.R423* | Nonsense Mutation (SNP) | VAF 91/235 reads (39%) | called by muse, mutect2, varscan2
- CPA2 | c.1025G>C p.S342T | Missense Mutation (SNP) | VAF 178/701 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- DSCAML1 | c.4865A>G p.E1622G (on ENST00000321322; = p.E1562G on NM_020693.4) | Missense Mutation (SNP) | VAF 25/647 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2
- E2F8 | c.252T>G p.F84L | Missense Mutation (SNP) | VAF 196/865 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FEN1 | c.281C>A p.S94* | Nonsense Mutation (SNP) | VAF 123/646 reads (19%) | called by muse, mutect2, varscan2
- FTSJ1 | c.794C>G p.P265R | Missense Mutation (SNP) | VAF 119/145 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- FUT4 | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 93/471 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- GPATCH2 | c.1144dup p.S382Ffs*8 | Frame Shift Ins (INS) | VAF 110/249 reads (44%) | called by mutect2, pindel, varscan2
- INSM1 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 144/483 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IRX6 | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 121/309 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- KIR3DL1 | c.822A>C p.R274S | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- MYOM2 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 112/921 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- NCOR2 | c.4520G>T p.S1507I | Missense Mutation (SNP) | VAF 127/482 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- OR52R1 | c.112T>A p.Y38N | Missense Mutation (SNP) | VAF 171/654 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- PCF11 | c.2662G>T p.G888C | Missense Mutation (SNP) | VAF 83/299 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PRSS2 | c.689C>G p.T230S | Missense Mutation (SNP) | VAF 122/712 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); called by muse, varscan2
- PSMD3 | c.42G>T p.K14N | Missense Mutation (SNP) | VAF 140/488 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- RFX3 | c.449A>G p.H150R | Missense Mutation (SNP) | VAF 112/292 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- SI | c.1399G>C p.V467L | Missense Mutation (SNP) | VAF 52/244 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); called by muse, mutect2
- SOS1 | c.2098C>T p.H700Y | Missense Mutation (SNP) | VAF 101/401 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYT16 | c.698C>G p.T233R | Missense Mutation (SNP) | VAF 90/247 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TESK2 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 99/295 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- TEX15 | c.91G>A p.E31K (on ENST00000638951; = p.E27K on NM_001350162.2) | Missense Mutation (SNP) | VAF 119/832 reads (14%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- TRIM71 | c.826G>A p.G276S | Missense Mutation (SNP) | VAF 82/209 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UBC | c.633C>A p.Y211* | Nonsense Mutation (SNP) | VAF 114/261 reads (44%) | called by muse, mutect2, varscan2
- VPS13B | c.4696C>T p.P1566S | Missense Mutation (SNP) | VAF 109/751 reads (15%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF624 | c.1841G>A p.C614Y | Missense Mutation (SNP) | VAF 111/388 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- FAM184B | c.207G>C p.A69= | Silent (SNP) | VAF 127/372 reads (34%) | catalogued as rs1011369904, COSV53954027; called by muse, mutect2, varscan2
- KLHDC7A | c.2028C>T p.N676= | Silent (SNP) | VAF 79/210 reads (38%) | catalogued as rs563995322, COSV68770583; called by muse, mutect2, varscan2
- KRT10 | c.1506A>G p.G502= | Silent (SNP) | VAF 39/218 reads (18%) | called by mutect2, varscan2
- OR2L8 | c.360T>C p.D120= | Silent (SNP) | VAF 33/580 reads (6%) | called by muse, mutect2
- OSBPL1A | c.2424C>T p.S808= (on ENST00000319481 / NM_080597.4; = p.S295= on NM_018030.4) | Silent (SNP) | VAF 81/178 reads (46%) | called by muse, mutect2, varscan2
- VPS54 | c.78G>A p.P26= | Silent (SNP) | VAF 121/542 reads (22%) | catalogued as rs751756431; called by muse, mutect2, varscan2
- ARL4C | c.*128G>A | 3'UTR (SNP) | VAF 74/210 reads (35%) | catalogued as rs957863789; called by muse, mutect2, varscan2
- C3orf52 | c.-4G>T | 5'UTR (SNP) | VAF 170/400 reads (43%) | catalogued as rs1355172364; called by muse, mutect2, varscan2
- EIF1AY | c.*80G>A | 3'UTR (SNP) | VAF 119/277 reads (43%) | called by muse, mutect2, varscan2
- FAM13A | c.*81C>T | 3'UTR (SNP) | VAF 23/47 reads (49%) | called by muse, mutect2, varscan2
- FAM157A | n.12G>T | RNA (SNP) | VAF 239/536 reads (45%) | called by mutect2, varscan2
- FOXD4L3 | c.*82T>A | 3'UTR (SNP) | VAF 30/266 reads (11%) | called by muse, mutect2
- GLYR1 | c.1282+82C>T | Intron (SNP) | VAF 46/85 reads (54%) | catalogued as rs562301356; called by muse, mutect2, varscan2
- LACC1 | c.*225A>G | 3'UTR (SNP) | VAF 37/91 reads (41%) | called by muse, mutect2, varscan2
- MRPL44 | c.*45T>G | 3'UTR (SNP) | VAF 73/246 reads (30%) | catalogued as rs548023128; called by muse, mutect2, varscan2
- OTOP2 | c.509+58G>T | Intron (SNP) | VAF 56/198 reads (28%) | called by muse, mutect2, varscan2
- SOX12 | c.*40G>A | 3'UTR (SNP) | VAF 26/111 reads (23%) | called by muse, mutect2, varscan2
- ZNF19 | c.34-35A>T | Intron (SNP) | VAF 31/55 reads (56%) | catalogued as rs1184493191; called by muse, mutect2, varscan2
